Surgical pathology report (de-identified scan), TCGA case TCGA-DV-5575, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DV-5575-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS:

- 1. "Left kidney tumor" (excision): Renal cell carcinoma, clear cell type, Furhman nuclear grade II.
- 2. "Cyst wall" (excision): Cystic kidney lesion with denudation of the lining and fibrosis of the wall.
- 3. "Base of cyst" (excision): Cystic kidney lesion with denudation of the lining and fibrosis of the wall.

NOTE:

CLINICAL INFORMATION: Brief Clinical History: VHL patient with left solid renal mass
Requestor Name proano [redacted] Specimen Taken
For Protocol: [redacted] - Yes Allocate Order to Protocol: [redacted]

PROCEDURE: Operative Findings: left renal mass Post-Operative Diagnosis: left renal masses Pre-Operative Diagnosis: Left renal masses

SPECIMENS SUBMITTED: 1. TUMOR, Left kidney
2. CYST, Wall
3. CYST, Base

GROSS DESCRIPTION: Received are three formalin-filled containers labeled with the patient's name, medical record number, and further described as follows:

Patient Identification	[redacted]
------------------------	-----------------------

[page 2 of 2]
1. "Left kidney tumor". The specimen consists of a red/brown nodule of tissue measuring 2.4 x 2.6 x 1.8 cm, with a small thin piece of brown tissue attached measuring 1.1 x 0.8 x 0.2 cm. Bisection reveals a heterogeneous yellow and red mottled cut surface. 50% of the nodule is procured for [REDACTED] and the remaining is sent to Surgical Pathology. The procurement was done by [REDACTED] on [REDACTED]. In Surgical Pathology, the specimen received matches the above description. The specimen is serially sectioned and representative sections submitted in white cassettes labeled [REDACTED] 1B for permanent processing.
2. "Cyst wall". The specimen consists of a flat sheet of pink/tan tissue measuring 6.6 x 2.2 x 0.1 cm. A piece of tissue measuring 1.0 x 0.5 x 0.1 cm is procured for [REDACTED] and remaining is sent to Surgical Pathology. Procurement was done by [REDACTED]. In Surgical Pathology, the specimen received matches the above description. The specimen is serially sectioned and representative sections are submitted in white cassette labeled [REDACTED] for permanent processing.
3. "Base of cyst". The specimen consists of a flat thin piece of tissue measuring 3 x 2.4 cm to a thickness of less than 1 cm. The specimen has two holes in the center with fibrous tissue attached. The specimen is sectioned and representative sections are submitted in white cassette labeled [REDACTED] for permanent process.

[REDACTED]

No consultants

Patient Identification

Source: NCI Genomic Data Commons file 12f10461-73e0-4406-8f42-1d53381ea95b (TCGA-DV-5575.C2EB12F1-4DD2-4B93-8A40-B81F9BE13EA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).